Gene-level copy-number profile of tumor specimen TCGA-ZJ-AAXJ-01A from TCGA case TCGA-ZJ-AAXJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Age at diagnosis: 43.8 years (16,007 days).
Specimen TCGA-ZJ-AAXJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.d7c8c6ec-eeb0-49f6-a016-b27c4e10810e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZJ-AAXJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/edc832ea-e744-41f1-a478-abb85f15b600

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,157; copy number 2: 40,976; copy number 3: 6,558; copy number 4: 1,799; copy number 5: 69; copy number 6: 204; copy number 8: 20; copy number 10: 31; copy number 18: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZJ-AAXJ-01A-11D-A42N-01): tumor purity 0.72, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 328 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:181,813,401–181,867,154, 4 genes, copy number 18: RN7SL703P, RNA5SP150, AC007547.2, AC007547.1.
- chr12:39,170,646–40,570,832, 19 genes, copy number 8: AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P.
- chr12:40,728,811–40,729,897, 1 gene, copy number 8: AC016144.1.
- chr12:64,507,001–70,354,993, 133 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr19:32,102,088–32,405,560, 6 genes, copy number 6: LINC01782, AC011518.1, AC074139.1, RNA5SP472, ZNF507, AC007773.1.
- chr19:37,735,833–39,598,002, 96 genes, copy number 6–10 (within-gene range 1–10) (broad region; genes not listed).
- chr19:44,141,554–45,478,828, 69 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,157. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
